Surgical pathology report (de-identified scan), TCGA case TCGA-EX-A69M, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of North Carolina, specimen TCGA-EX-A69M-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Uterus, cervix, bilateral tubes and ovaries, abdominal hysterectomy and bilateral salpingo-oophorectomy

Histologic type: invasive non-keratinizing squamous cell carcinoma of the cervix with lymphocytic response

Histologic grade: poorly differentiated

Tumor site: cervix, tumor involves the cervix circumferentially

Myometrium: uninvolved

Parametrium/serosal involvement: absent

Tumor size: tumor size grossly 5.8 cm; tumor invades to 2.4 out of 2.6 cm, invading most deeply within the posterior cervix (92% through the cervical wall, A2)

Adnexal involvement: absent

Cervical/vaginal margin and distance:

- Tumor extends most closely to 1.6 cm from the cervical/vaginal cuff margin
- CIN 3 extends to 1.5 cm from the cervical/vaginal cuff margin

Lymphovascular space invasion: absent

Regional lymph nodes (see other specimens):

Total number involved: 0

Total number examined: 11

Additional pathologic findings:

- CIN 3 with HPV effect
- Atrophic endometrium
- Myometrium with vascular calcifications

ICD-O-3
Carcinoma, squamous cell
non-keratinizing NOS 8672/3
Site: Cervix NOS C53.9
JW 5/16/13

Right ovary: atrophic ovary, no tumor seen

Left ovary: atrophic ovary with simple cyst, no tumor seen

Right fallopian tube: paratubal cyst, no tumor seen

Left fallopian tube: paratubal cyst, no tumor seen

AJCC Pathologic Stage: pT1b2 pN0 pMx

FIGO (2009 classification) Stage Grouping: IB2

[page 2 of 4]
Note: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

B: Lymph node, left pelvic, dissection
- Five lymph nodes, no tumor seen (0/5)

C: Lymph node, right pelvic, dissection
- Six lymph nodes, no tumor seen (0/6)

Clinical History:

The patient is a -year-old female with a clinical diagnosis of adenocarcinoma.

Gross Description:

Received are three appropriately labeled containers.

Container A is additionally labeled "uterus, cervix, bilateral tubes and ovaries, parametrium."

Specimen fixation: formalin

Specimen type: hysterectomy and bilateral salpingectomy

Adnexa: present and attached bilaterally

Weight: 155 grams

Shape: cylindrical

Dimensions:

Height: 11.5 cm

Anterior to posterior width: ranging from 2.5 to 4.5 cm

Breadth at fundus: 4.4 cm

Serosa: tan/pink with a defect at the fundus (0.8 cm x 0.4 cm)

Cervix:

Ectocervix: tan with focal hemorrhage and cautery artifact (diameter is 4.0 cm) with a centrally located os (1.5 cm)

Tumor size: 5.8 x 4.9 x 3.0 cm

Tumor site: The tumor comes within 0.1 cm of the black inked margin. The tumor is located circumferentially within each quadrant of the cervix.

Endocervix: tan with involvement by tumor

Other features: none

[page 3 of 4]
Endometrium:

Length of endometrial cavity: 3.5 cm

Width at fundus: 1.0 cm

Endometrial surface: red/tan and velvety; It is 0.1 cm thick.

Other findings: none

Myometrium:

Thickness of wall: 1.2 cm

Other findings: none

Adnexa:

Right ovary:

Measurement: 2.0 x 0.8 x 1.0 cm

External surface: tan/pink, smooth and glistening

Cut surface: homogeneous, tan/pink, unremarkable ovarian parenchyma

Right fallopian tube:

Measurement: length, 5.0 cm; diameter, 0.8 cm

Other findings: fimbria present, fallopian tube patent

Left ovary:

Measurement: 1.5 x 1.2 x 0.9 cm

External surface: tan/pink, smooth and glistening

Cut surface: — homogeneous unremarkable ovarian parenchyma compressed a cyst (1.0 cm in greatest dimension); The cyst walls are 0.1 cm thick with a shiny smooth interior. The cyst is filled with a serous fluid.

Left fallopian tube:

Measurement: length, 5.0 cm; width, 0.6 cm

Other findings: fimbria present, patent fallopian tube lumen

Other organs present:

Vagina: no

Urinary bladder: no

Rectum: no

Other comments: Right Parametrium (3.0 x 4.5 x 1.5 cm) and Left parametrium (2.0 x 3.8 x 2.0 cm) are present.

Digital picture: not taken

Tissue give to tissue procurement: Tissue was given to Tissue Procurement

[page 4 of 4]
Block summary:

A1 - perpendicular section of anterior cervix, tumor and margin
A2 - perpendicular section of posterior cervix, tumor and margin
A3 - cervical margin, en face (9 o' clock to 3 o' clock)
A4 - cervical margin, en face (6 o' clock to 9 o' clock)
A5 - cervical margin, en face (3 o' clock to 6 o' clock)
A6 - anterior lower uterine segment
A7 - posterior lower uterine segment
A8 - anterior corpus
A9 - posterior corpus
A10 - representative sections of right ovary and representative sections of right fallopian tube
A11 - bisected right fimbria and soft tissue
A12 - representative sections of left ovary
A13 - fimbria candidate, bisected
A14-A18 - right parametrium
A19-A26 - left parametrium
Tissue remains in the container.

Container B is additionally labeled "left pelvic nodes" and holds two fragments of yellow adipose tissue (in aggregate 4.6 x 3.7 x 1.8 cm). Within the fatty tissue, there are multiple firm lymph node candidates ranging in greatest dimension from 0.6 to 1.5 cm.

Block Summary:

B1 - Serially sectioned lymph node candidate
B2 - Three lymph node candidates
B3 - One lymph node candidate
B4 - One lymph node candidate
Tissue remains in container.

Container C is additionally labeled "right pelvic lymph nodes" and holds multiple fragments of yellow adipose tissue in aggregate 3.9 x 2.5 x 1.4 cm. Within the fatty tissue, there are multiple firm tan lymph node candidates (ranging in greatest dimension from 0.5 to 1.7 cm).

Block Summary:

C1 - Three lymph node candidates
C2 - Two lymph node candidates
C3-C4 - Serially sectioned largest lymph node candidates
Tissue remains in container.

Print Malignancy History		✓

4/30/13

Source: NCI Genomic Data Commons file be508a3e-a400-45ec-9653-64714d9fcbb7 (TCGA-EX-A69M.808A38A8-4E74-42A4-8258-C883A7F6CA0C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).